Gene-level copy-number profile of tumor specimen TCGA-AA-3952-01A from TCGA case TCGA-AA-3952, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.1 years (24,868 days).
Specimen TCGA-AA-3952-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.1cebf64c-95f4-4068-9b96-d53e0c19f846.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3952-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef93ee42-edd4-498b-991c-867efe8462f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 21,081; copy number 2: 33,016; copy number 3: 5,061; copy number 4: 101; copy number 5: 172; copy number 6: 34; copy number 7: 53; copy number 9: 111; copy number 10: 25; copy number 11: 57; copy number 12: 28; copy number 15: 6; copy number 18: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3952-01A-01D-1018-01): tumor purity 0.74, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,001,355–43,233,394, 10 genes: AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr3:2,362,258–2,362,738, 1 gene: HINT2P1.
- chr10:87,751,512–89,139,458, 33 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1.
- chr16:6,748,908–7,004,112, 3 genes: RNU7-99P, RNU6-457P, RNU6-328P.
- chr17:142,789–721,717, 16 genes (within-gene range 0–4): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17.
- chr19:14,583,084–14,612,035, 1 gene (within-gene range 0–1): CLEC17A.
- chr19:14,619,117–14,690,027, 3 genes (within-gene range 0–2): ADGRE3, ITGB1P1, AC022149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 493 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,953,590–121,580,524, 83 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:231,626,790–232,041,272, 1 gene, copy number 5 (within-gene range 1–5): DISC1.
- chr1:231,767,464–232,983,882, 16 genes, copy number 5: AL136171.2, AL136171.1, DISC1-IT1, AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2, RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2, AL122003.1, NTPCR.
- chr10:1,957,589–2,728,267, 13 genes, copy number 5: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1.
- chr10:74,151,202–82,987,179, 149 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr12:752,579–911,452, 1 gene, copy number 6 (within-gene range 1–6): WNK1.
- chr12:865,288–991,190, 3 genes, copy number 6: AC004765.1, RAD52, AC004803.1.
- chr12:1,946,053–4,615,302, 68 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr12:18,683,169–20,098,868, 21 genes, copy number 9 (within-gene range 1–9): PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398.
- chr16:24,537,693–29,370,272, 130 genes, copy number 5–18 (within-gene range 3–18) (broad region; genes not listed).
- chr20:20,214,299–20,712,644, 8 genes, copy number 5 (within-gene range 2–5): AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1.

Autosomal genes at a single copy (total copy number 1): 18,694. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
